Somatic mutation profile of tumor specimen 0DVSBZ from CCDI case PBCNEI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Age at diagnosis: 5.6 years (2,042 days).
Specimen 0DVSBZ: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f4db58b-014d-4dee-b2f8-2deb2a563155.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSCF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90df2901-099a-4f9c-9948-c3f3d5d57483

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 2, Splice Site 2, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0D2 | c.302+1G>A p.X101_splice | Splice Site (SNP) | VAF 22/190 reads (12%) | catalogued as rs760220576, COSV53413110; called by muse, mutect2, varscan2
- BCHE | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 72/577 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs962126690, COSV100013035; called by muse, mutect2, varscan2
- DNAH6 | c.10682G>A p.R3561K | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1466223583; called by muse, mutect2, varscan2
- FOXP1 | c.1146C>A p.P382= | Splice Region (SNP) | VAF 23/220 reads (10%) | catalogued as rs372765119; called by muse, mutect2, varscan2
- GAMT | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as COSV52039955; called by muse, mutect2
- HSD17B8 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs755014412; called by mutect2, varscan2
- ITPR2 | c.1675G>C p.V559L | Missense Mutation (SNP) | VAF 43/430 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.205); catalogued as rs752387178; called by muse, mutect2, varscan2
- NES | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 43/301 reads (14%) | catalogued as COSV63961601; called by muse, mutect2, varscan2
- PML | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1252142924; called by muse, mutect2, varscan2
- ABHD17B | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, varscan2
- ANK2 | c.9338G>A p.R3113Q | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC168 | c.16629T>G p.D5543E | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2
- DDX42 | c.1802T>C p.L601P | Missense Mutation (SNP) | VAF 62/517 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND1B | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 64/603 reads (11%) | called by muse, mutect2, varscan2
- FAM91A1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MECOM | c.889C>A p.P297T (on ENST00000468789 / NM_001105078.4; = p.P485T on NM_004991.4) | Missense Mutation (SNP) | VAF 66/540 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NLRP9 | c.1802T>A p.I601N | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- NUP205 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- OR10H2 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- OVOL2 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2
- TAS2R16 | c.294G>T p.L98F | Missense Mutation (SNP) | VAF 57/518 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TSR1 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 125/448 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP34 | c.4833-1G>C p.X1611_splice | Splice Site (SNP) | VAF 58/356 reads (16%) | called by muse, mutect2, varscan2
- MUC5B | c.7941G>T p.V2647= | Silent (SNP) | VAF 60/760 reads (8%) | called by muse, mutect2
- OR10J3 | c.381C>A p.I127= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- OR2L2 | c.81C>T p.F27= | Silent (SNP) | VAF 110/443 reads (25%) | called by muse, mutect2, varscan2
- SLC5A1 | c.1656G>A p.P552= | Silent (SNP) | VAF 38/344 reads (11%) | catalogued as rs375169164; called by muse, mutect2, varscan2
- VIT | c.1623C>T p.Y541= (on ENST00000389975 / NM_001177969.1; = p.Y556= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/620 reads (9%) | catalogued as rs201460204, COSV64895465; called by muse, mutect2
- BMP6 | c.-13C>T | 5'UTR (SNP) | VAF 34/253 reads (13%) | catalogued as rs1198192468; called by muse, mutect2, varscan2
- IQCA1L | c.-17G>T | 5'UTR (SNP) | VAF 33/358 reads (9%) | called by muse, mutect2
